Somatic mutation profile of tumor specimen TCGA-G3-AAV6-01A (aliquot TCGA-G3-AAV6-01A-21D-A36X-10) from TCGA case TCGA-G3-AAV6, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 53.5 years (19,556 days).
Specimen TCGA-G3-AAV6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5b6a05c-1a7e-45e7-a827-504541bf71bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV6-10A (Blood Derived Normal), aliquot TCGA-G3-AAV6-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b77914a5-8813-4456-aa30-63305b0cb7e1

The open-access MAF lists 81 somatic variants for this specimen: 54 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 26, Nonsense Mutation 3, In Frame Del 3, Splice Site 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 43/111 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1481695656, COSV99521863; called by muse, mutect2, varscan2
- AC093525.2 | c.993A>C p.Q331H | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV99565857; called by muse, mutect2, varscan2
- ADGRG4 | c.2789T>C p.M930T | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99795495; called by muse, mutect2, varscan2
- ADGRL4 | c.1886C>A p.T629N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100875958, COSV66065106; called by muse, mutect2, varscan2
- ALK | c.1354G>T p.G452W | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV101201961, COSV66594960; called by muse, mutect2, varscan2
- AMPH | c.1288G>C p.A430P | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100342141; called by muse, mutect2, varscan2
- ANKRD6 | c.247A>C p.T83P | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100329892; called by muse, mutect2, varscan2
- ATG7 | c.1823G>T p.S608I | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV100607303, COSV61612070; called by muse, mutect2
- ATP10D | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.345); catalogued as COSV99905615; called by muse, mutect2, varscan2
- BCLAF3 | c.668A>T p.D223V | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100503301; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3980C>A p.T1327N | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100863762; called by muse, mutect2, varscan2
- BMS1 | c.2541T>G p.Y847* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as rs771464519, COSV100996708; called by muse, mutect2, varscan2
- CNTNAP2 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100666650, COSV62233530; called by muse, mutect2, varscan2
- COL12A1 | c.3112C>A p.Q1038K | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV100486000; called by muse, mutect2, varscan2
- CRTAC1 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV100085538; called by muse, mutect2
- CSDE1 | c.390C>G p.Y130* | Nonsense Mutation (SNP) | VAF 88/632 reads (14%) | catalogued as COSV99794986; called by muse, mutect2, varscan2
- CWC27 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101126495; called by muse, mutect2, varscan2
- CYP1B1 | c.678C>G p.S226R | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV99572689; called by muse, mutect2
- DAZAP1 | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99245237; called by muse, mutect2, varscan2
- DCTN1 | c.626C>G p.P209R | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.422); catalogued as rs112725508, COSV100720951; called by muse, mutect2, varscan2
- DMXL1 | c.4106G>A p.R1369H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs776741081, COSV60705181; called by muse, mutect2, varscan2
- FKRP | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV59358275; called by muse, mutect2, varscan2
- FZD7 | c.1555C>T p.H519Y | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99637188; called by muse, mutect2, varscan2
- GAS7 | c.615+2T>C p.X205_splice (on ENST00000432992 / NM_201433.2; = p.X65_splice on NM_003644.3) | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100095522; called by muse, mutect2, varscan2
- HMG20A | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV60311321; called by muse, mutect2, varscan2
- IQSEC1 | c.2847A>C p.E949D | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV99831904; called by muse, mutect2
- KDM3A | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100460425; called by muse, mutect2, varscan2
- KRT6B | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs756620061, COSV99360708; called by muse, mutect2, varscan2
- LRP1B | c.4423G>T p.V1475L | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as COSV101257110; called by muse, mutect2, varscan2
- MISP | c.1391C>T p.T464M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs781240965, COSV99296826; called by muse, mutect2, varscan2
- NOP9 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV99852299; called by muse, mutect2, varscan2
- OPN4 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs150092638, COSV99618068; called by muse, mutect2, varscan2
- PHF14 | c.2251C>G p.H751D | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101301808; called by muse, mutect2, varscan2
- POLRMT | c.2018C>T p.T673M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); catalogued as rs1304580366, COSV99241824; called by muse, mutect2, varscan2
- PRICKLE1 | c.2312A>T p.D771V | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100453810; called by muse, mutect2, varscan2
- PSMA3 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV99373424; called by muse, mutect2, varscan2
- PTPN14 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs759897774, COSV65289939; called by muse, mutect2, varscan2
- QSER1 | c.1139G>T p.G380V (on ENST00000399302; = p.G509V on NM_001076786.3) | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV67899945; called by muse, mutect2
- RAB8B | c.292A>G p.N98D | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100368950; called by muse, mutect2, varscan2
- RPGR | c.1508C>A p.T503K | Missense Mutation (SNP) | VAF 70/366 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100139998; called by muse, mutect2, varscan2
- SEC31B | c.2229G>T p.R743S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100947320; called by muse, mutect2, varscan2
- STK32A | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100097063, COSV60417388; called by muse, mutect2, varscan2
- TBX22 | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100960773; called by muse, varscan2
- TCP11L1 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100178138; called by muse, mutect2, varscan2
- TMF1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as rs1413380367, COSV100734689; called by muse, mutect2
- TNS4 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.253); catalogued as rs772361427, COSV99563841; called by muse, mutect2, varscan2
- UBA52 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as COSV99723667; called by muse, mutect2, varscan2
- XPO1 | c.1836T>G p.D612E | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV101294216; called by muse, mutect2, varscan2
- ZNF91 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV100322716; called by muse, mutect2, varscan2
- ABCA10 | c.694_717del p.S232_M239del | In Frame Del (DEL) | VAF 52/449 reads (12%) | called by mutect2, pindel
- GJB1 | c.89_94dup p.I30_F31dup | In Frame Ins (INS) | VAF 32/85 reads (38%) | called by mutect2, varscan2
- NKAP | c.1164_1166del p.E389del | In Frame Del (DEL) | VAF 22/85 reads (26%) | called by pindel, varscan2
- PNPT1 | c.1832_1837del p.Q611_V612del | In Frame Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ABCA3 | c.2493C>T p.T831= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100068491; called by muse, mutect2, varscan2
- ACTL7B | c.408C>T p.T136= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as rs1315798846, COSV101012597, COSV65927188; called by muse, mutect2, varscan2
- AMPH | c.1899T>C p.F633= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100342138; called by muse, mutect2, varscan2
- AQP12A | c.213C>T p.H71= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as rs145149435; called by muse, mutect2, varscan2
- CBFA2T3 | c.183G>T p.A61= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99241834; called by muse, mutect2, varscan2
- CFAP65 | c.2475T>G p.T825= | Silent (SNP) | VAF 28/215 reads (13%) | catalogued as COSV100445146; called by muse, mutect2, varscan2
- CTXN3 | c.198T>C p.D66= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV101060671; called by muse, mutect2, varscan2
- CYP2B6 | c.723C>T p.I241= | Silent (SNP) | VAF 109/523 reads (21%) | catalogued as COSV100137565; called by muse, mutect2, varscan2
- DNAH2 | c.5601G>A p.V1867= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV101209321; called by muse, mutect2, varscan2
- EGR2 | c.565C>T p.L189= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV99654129; called by muse, mutect2
- ERCC6 | c.2715A>G p.T905= | Silent (SNP) | VAF 70/208 reads (34%) | catalogued as COSV100875940; called by muse, mutect2, varscan2
- FBXW5 | c.996C>G p.A332= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99812501; called by muse, mutect2, varscan2
- GAS2L2 | c.1554C>T p.S518= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- IL17RA | c.2130C>T p.G710= | Silent (SNP) | VAF 108/289 reads (37%) | catalogued as COSV100083137; called by muse, mutect2
- KIZ | c.756G>A p.L252= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as COSV99852077; called by muse, mutect2
- MZT2B | c.438G>A p.G146= | Silent (SNP) | VAF 53/364 reads (15%) | catalogued as COSV56058218; called by muse, mutect2, varscan2
- NFKBIB | c.747G>A p.V249= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100548371; called by mutect2, varscan2
- NLRP11 | c.1125T>A p.A375= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100789735; called by muse, mutect2, varscan2
- PLXNB3 | c.3414G>T p.G1138= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV100737455; called by muse, mutect2, varscan2
- ROR2 | c.1629G>A p.V543= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100995819; called by muse, mutect2, varscan2
- RTN1 | c.1713G>T p.G571= | Silent (SNP) | VAF 21/178 reads (12%) | catalogued as COSV99955686; called by muse, mutect2, varscan2
- SOX13 | c.1527C>T p.R509= | Silent (SNP) | VAF 55/277 reads (20%) | catalogued as rs750845374, COSV99689958; called by muse, mutect2, varscan2
- SYDE1 | c.1974C>T p.C658= | Silent (SNP) | VAF 55/124 reads (44%) | catalogued as rs760620825, COSV54619928; called by muse, varscan2
- TAS2R41 | c.144C>T p.L48= | Silent (SNP) | VAF 88/145 reads (61%) | catalogued as rs1337659558, COSV101281490; called by muse, mutect2, varscan2
- ZHX3 | c.1359G>A p.Q453= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as COSV100476054; called by muse, mutect2
- ZNF208 | c.213G>T p.V71= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV101237024; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827689 A>G | 3'Flank (SNP) | VAF 60/313 reads (19%) | catalogued as COSV100157372, COSV100157771; called by muse, mutect2, varscan2
